Somatic mutation profile of tumor specimen C3L-02115-02 (aliquot CPT0109110012_1) from CPTAC case C3L-02115, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.0 years (29,237 days).
Specimen C3L-02115-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8b98a1c-d91d-4657-8235-1013f558e56f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02115-31 (Blood Derived Normal), aliquot CPT0109140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeb374c5-96d8-4e15-8d74-2e6e3fec519e

The open-access MAF lists 31 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 11, Nonsense Mutation 2, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 54/562 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CLCN2 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 18/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1378624035; called by muse, mutect2
- EPPK1 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782124026, COSV73260765, COSV73262458; called by muse, mutect2
- FGF12 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 20/556 reads (4%) | catalogued as COSV53168042; called by muse, mutect2
- GAL3ST2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 18/515 reads (3%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.891); catalogued as rs1489053896; called by muse, mutect2
- KLF16 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1483372317, COSV51737011; called by muse, mutect2
- PCDHA5 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 47/1116 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100972129; called by muse, mutect2
- PTPRD | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100643981; called by muse, mutect2
- SMAD4 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM144214, COSV61684333; called by muse, mutect2
- VANGL2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 24/643 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63604324; called by muse, mutect2
- WDR19 | c.3211A>G p.T1071A | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.119); catalogued as rs1463002459; called by muse, mutect2
- HMX1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- OR6K6 | c.973A>G p.K325E (on ENST00000368144; = p.K301E on NM_001005184.1) | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- PODNL1 | c.717C>G p.Y239* | Nonsense Mutation (SNP) | VAF 25/660 reads (4%) | called by muse, mutect2
- RTN2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 28/680 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- THEGL | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2
- TRIM49B | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 27/737 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ABI1 | c.1170T>A p.A390= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- DSCAM | c.2937G>A p.A979= | Silent (SNP) | VAF 26/687 reads (4%) | catalogued as rs1031920480, COSV68027706; called by muse, mutect2
- ELMO1 | c.1326C>T p.H442= | Silent (SNP) | VAF 10/299 reads (3%) | called by muse, mutect2
- FLNB | c.2535C>T p.A845= | Silent (SNP) | VAF 15/523 reads (3%) | called by muse, mutect2
- GUCY2D | c.321G>A p.T107= | Silent (SNP) | VAF 20/506 reads (4%) | called by muse, mutect2
- IGHV4-28 | c.123C>T p.C41= | Silent (SNP) | VAF 32/778 reads (4%) | catalogued as rs376044890; called by muse, mutect2
- LRAT | c.249C>T p.D83= | Silent (SNP) | VAF 14/404 reads (3%) | catalogued as COSV60478098; called by muse, mutect2
- SACS | c.8467A>C p.R2823= | Silent (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- SRRM3 | c.993G>A p.A331= | Silent (SNP) | VAF 11/167 reads (7%) | catalogued as rs1554609932; called by muse, mutect2
- TINAG | c.141C>T p.F47= | Silent (SNP) | VAF 21/616 reads (3%) | catalogued as COSV52505035; called by muse, mutect2
- TM6SF2 | c.1074C>T p.P358= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs199962010; called by muse, mutect2
- FAM215A | n.360C>T | RNA (SNP) | VAF 17/360 reads (5%) | called by muse, mutect2
- NAGLU | chr17:42547094 G>A | 3'Flank (SNP) | VAF 13/412 reads (3%) | catalogued as rs796707265; called by muse, mutect2
- STMND1 | c.82-4095G>A | Intron (SNP) | VAF 8/180 reads (4%) | catalogued as rs1437975802; called by muse, mutect2
